Somatic mutation profile of tumor specimen TCGA-AR-A1AJ-01A (aliquot TCGA-AR-A1AJ-01A-21D-A12Q-09) from TCGA case TCGA-AR-A1AJ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-AR-A1AJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd17825e-9bcc-4ed5-ae9f-b8e3bd3b9d59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A1AJ-10A (Blood Derived Normal), aliquot TCGA-AR-A1AJ-10A-01D-A12Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f083021c-ee0d-4579-bda2-8375f7175409

The open-access MAF lists 37 somatic variants for this specimen: 31 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 4, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 31/155 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF15 | c.288C>G p.S96R | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV62724922; called by muse, mutect2, varscan2
- BAIAP3 | c.1940C>T p.T647M | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.036); catalogued as rs368548091; called by muse, mutect2, varscan2
- C19orf18 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 22/427 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100071867; called by muse, mutect2
- CEP162 | c.2142G>C p.E714D | Missense Mutation (SNP) | VAF 64/864 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100003001; called by muse, mutect2
- DCAF8L1 | c.428T>A p.I143N | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV71595230; called by muse, mutect2
- DMXL1 | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100224351, COSV60708421; called by muse, mutect2
- EFCAB3 | c.145A>G p.M49V | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1312792696, COSV59501194; called by muse, mutect2, varscan2
- ENTR1 | c.797C>G p.T266R (on ENST00000357365 / NM_001039707.2; = p.T243R on NM_006643.4) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV53741209; called by muse, mutect2, varscan2
- FLG | c.5041C>T p.H1681Y | Missense Mutation (SNP) | VAF 34/348 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV64240412; called by muse, mutect2, varscan2
- GABRA3 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100942991; called by muse, mutect2
- HACD2 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101046016; called by muse, mutect2
- HERC2 | c.3176G>A p.R1059H | Missense Mutation (SNP) | VAF 47/281 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV55305878; called by muse, mutect2, varscan2
- KCNQ2 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as rs1312940969, COSV60433201; called by muse, mutect2, varscan2
- MIB1 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV55089661; called by muse, mutect2, varscan2
- NOX1 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs769691003, COSV54193967, COSV54195027; called by muse, mutect2, varscan2
- P4HTM | c.533A>C p.E178A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as COSV59086677; called by muse, mutect2, varscan2
- PCSK1 | c.2245C>G p.L749V | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.203); catalogued as COSV100227163; called by muse, mutect2
- PIK3C2A | c.185G>C p.R62T | Missense Mutation (SNP) | VAF 50/550 reads (9%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.01); catalogued as COSV99790930; called by muse, mutect2
- PTEN | c.28A>C p.S10R | Missense Mutation (SNP) | VAF 49/290 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV64290189, COSV64294948; called by muse, mutect2, varscan2
- QRFPR | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs543792498, COSV57678125, COSV57678536; called by muse, mutect2
- RAD51AP2 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV101208372; called by muse, mutect2, varscan2
- RAPGEF6 | c.94C>G p.L32V | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV57242624, COSV99726884; called by muse, mutect2
- SDK1 | c.2764A>G p.T922A | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as rs140259802; called by muse, mutect2, varscan2
- SPINK5 | c.2687G>C p.R896T | Missense Mutation (SNP) | VAF 10/277 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56254616, COSV99806050, COSV99806965; called by muse, mutect2
- TTN | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 18/182 reads (10%) | PolyPhen benign (0.112); catalogued as COSV100619176; called by muse, mutect2
- VPS37C | c.842G>C p.G281A | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100075223; called by muse, mutect2
- WWC2 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs974533739, COSV66713195; called by muse, mutect2, varscan2
- XIRP2 | c.19C>G p.H7D (on ENST00000628543; = p.H182D on NM_152381.6) | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.298); catalogued as COSV99744578; called by muse, mutect2
- MAFB | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 2/13 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- SARM1 | c.1438del p.S480Lfs*101 | Frame Shift Del (DEL) | VAF 4/13 reads (31%) | called by muse*, mutect2
- DGKB | c.2109G>A p.L703= | Silent (SNP) | VAF 18/362 reads (5%) | catalogued as COSV51793320, COSV99340835; called by muse, mutect2
- DNAH5 | c.11586G>A p.P3862= | Silent (SNP) | VAF 19/166 reads (11%) | catalogued as rs755874851, COSV54218580; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MMEL1 | c.984C>T p.V328= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV99984014; called by muse, mutect2, varscan2
- WT1 | c.708G>A p.T236= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs768828897, COSV60070198; ClinVar: likely benign; called by muse, mutect2, varscan2
- RBFOX1 | c.28-185137G>A | Intron (SNP) | VAF 39/289 reads (13%) | catalogued as rs771567004, COSV60946776, COSV60951877; called by muse, mutect2, varscan2
- VGLL1 | c.688+108A>T | Intron (SNP) | VAF 55/297 reads (19%) | catalogued as COSV65703190; called by muse, mutect2, varscan2
